TCGA case TCGA-J8-A3YG — Thyroid Carcinoma (TCGA-THCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Thyroid gland; Tissue source site: Mayo Clinic. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/9aa61ab5-f675-43dd-8a99-077164b41f30

Demographics
Sex at birth: female; Race: white; Country of residence at enrollment: United States; Age at index: 54 years; Vital status: Alive.

Diagnoses (1)
1. Papillary adenocarcinoma, NOS: ICD-O-3 morphology code: 8260/3; ICD-10 code: C73; Tissue or organ of origin: Thyroid gland; Site of resection or biopsy: Thyroid gland; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 54.2 years (19,785 days); Year of diagnosis: 2010; AJCC staging edition: 7th; AJCC pathologic T: T2; AJCC pathologic N: N1a; AJCC pathologic M: M0; AJCC pathologic stage: Stage III; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 678 days (1.9 years); Tumor focality: Multifocal.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 6; Lymph nodes tested: 9; Measurement unit: Centimeters; Tumor depth measurement: 1.6; Tumor length measurement: 2.5; Tumor width measurement: 2.
   Treatment given: Treatment type: Radiation, Systemic; Days to treatment start: 110 days; Days to treatment end: 110 days; Treatment dose: 157 mCi; Treatment outcome: Partial Response; Number of fractions: 1; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: I-131 Radiation Therapy; Treatment intent type: Adjuvant; Treatment dose: 157 mCi; Pretreatment: Thyroxine Withdrawal.
   Treatment given: Treatment type: I-131 Radiation Therapy; Treatment intent type: Adjuvant; Prescribed dose: 157; Prescribed dose units: mCi; Pretreatment: Thyroxine Withdrawal; Timepoint category: First Treatment.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation, External Beam.

Follow-up (4 entries)
- Days to follow up: 678 days (1.9 years); Disease response: Tumor Free.
- Imaging type: CT Scan; Imaging anatomic site: Lymph Node; Timepoint: Preoperative.
- Imaging type: Ultrasound; Imaging anatomic site: Lymph Node; Timepoint: Preoperative.
- Disease response: Complete Response; Timepoint: Within 3 Months of Surgery.

Molecular and laboratory tests
- BRAF mutation, nos: Positive.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-J8-A3YG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 60 mg.
  Slide TCGA-J8-A3YG-01A-01-TS1: Section location: Top; Percent tumor cells: 50; Percent tumor nuclei: 85; Percent normal cells: 15; Percent necrosis: 0; Percent stromal cells: 35; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 0.
- Sample TCGA-J8-A3YG-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-J8-A3YG-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; History radiation exposure: No; Submitted tumor site: Thyroid; Histologic diagnosis: Thyroid Papillary Carcinoma - Classical/usual; Lymph nodes preop imaging: Yes; Lymph nodes examined: Yes; Genotypic analysis detected: Yes; I 131 radiation first treatment dose: 157 millicuries; I 131 radiation treatment cumulative dose: 157 millicuries; Radiation therapy xrt method prep: Patient Did Not Receive External Radiation Therapy; Clinical status within 3 mths surgery: No imaging evidence of disease; New tumor event diagnosis indicator: No.
- Neoplasm dimension: Tumor size width: 2.0.
- Lymph node preoperative assessment diagnostic imaging types: Lymph nodes preop imaging type: CT with contrast.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 678 days; disease-specific survival: no event (censored), 678 days; disease-free interval: no event (censored), 678 days; progression-free interval: no event (censored), 678 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-J8-A3YG-01A-11D-A22Y-01): tumor purity 0.37, ploidy 2, whole-genome doublings 0.
